Somatic mutation profile of tumor specimen ALCH-B27N-TTP1-A (aliquot ALCH-B27N-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B27N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,255 days).
Specimen ALCH-B27N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bc86a49-aff8-4014-81f9-5d24b13acb56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27N-NB1-A (Blood Derived Normal), aliquot ALCH-B27N-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3f7f086-e085-4543-920d-44b00e9367a3

The open-access MAF lists 217 somatic variants for this specimen: 149 protein-altering or splice-affecting, 46 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 46, Nonsense Mutation 13, Intron 10, 3'UTR 4, Splice Region 3, RNA 3, 5'Flank 2, 3'Flank 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 951/1447 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 33/327 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP5 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54536259, COSV54536728; called by muse, mutect2
- ADAMTS16 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV56978976; called by muse, mutect2
- AGAP2 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 30/171 reads (18%) | catalogued as rs1555199972; called by muse, mutect2, varscan2
- ANKRD18A | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV68803601, COSV68803607; called by muse, mutect2
- ARMC5 | c.2485G>T p.G829C | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51659496; called by muse, mutect2, varscan2
- AZIN1 | c.29A>G p.Y10C | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1309797017; called by muse, varscan2
- BDH1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100827194, COSV64017737; called by muse, mutect2
- BPTF | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58843287; called by muse, mutect2
- CCDC191 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.116); catalogued as COSV55675421; called by muse, mutect2
- CDC7 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99319485; called by muse, mutect2
- CEP192 | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 16/339 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs1242994378, COSV100380555, COSV58066186; called by muse, mutect2
- COL1A1 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 17/561 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99866338; called by muse, mutect2
- CSRP3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1476459032; called by muse, mutect2
- DNAH17 | c.11223G>A p.M3741I | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67753879; called by muse, mutect2
- DST | c.13391G>T p.G4464V (on ENST00000361203 / NM_001374722.1; = p.G2052V on NM_015548.5) | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.623); catalogued as rs748551099; called by muse, mutect2
- FAM126B | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99627418; called by muse, mutect2, varscan2
- FAM13A | c.2216G>A p.S739N | Missense Mutation (SNP) | VAF 54/379 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52010683; called by muse, mutect2, varscan2
- FAT3 | c.8732C>G p.S2911C | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV53113191; called by muse, mutect2
- FMN1 | c.3283G>A p.E1095K (on ENST00000616417 / NM_001277313.2; = p.E872K on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV57923267; called by muse, mutect2
- FSCN3 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99757047; called by muse, mutect2
- FUBP3 | c.1606C>G p.Q536E | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.08); catalogued as COSV60516265; called by muse, mutect2, varscan2
- GC | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs1370255063; called by muse, mutect2
- HTR5A | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 17/462 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.041); catalogued as rs1350441527, COSV55282641; called by muse, mutect2
- IGDCC4 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 50/667 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV61535670; called by muse, mutect2
- IQCJ-SCHIP1 | c.299G>A p.R100Q (on ENST00000485419 / NM_001197113.1; = p.R24Q on NM_014575.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1470180169; called by muse, mutect2
- IRF2BP1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV56194048; called by muse, mutect2
- ITPR1 | c.5912G>C p.R1971P (on ENST00000354582; = p.R1916P on NM_002222.7) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57008498; called by muse, mutect2, varscan2
- JUP | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV60279912; called by muse, mutect2
- KCNF1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs1337505283, COSV99705759, COSV99705791; called by muse, mutect2, varscan2
- KIAA0232 | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56929745; called by muse, varscan2
- KIF20B | c.5357C>T p.S1786L (on ENST00000371728 / NM_001284259.2; = p.S1746L on NM_016195.4) | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV53314571; called by muse, mutect2
- KLHL22 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as COSV100186125; called by muse, mutect2
- LRRFIP1 | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1272473757; called by muse, mutect2, varscan2
- MAN1A1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV100870608; called by muse, mutect2
- MED29 | c.226G>A p.D76N (on ENST00000615911; = p.D55N on NM_017592.4) | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55395692; called by muse, mutect2, varscan2
- MLEC | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs1184411173, COSV99949681; called by muse, mutect2, varscan2
- MMRN1 | c.3337A>C p.I1113L | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53341477; called by muse, varscan2
- PDE3B | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs1358945230; called by muse, mutect2, varscan2
- PDE6B | c.927+3G>T | Splice Region (SNP) | VAF 11/117 reads (9%) | catalogued as COSV99728467; called by muse, mutect2
- PIK3C2B | c.4219G>C p.E1407Q | Missense Mutation (SNP) | VAF 44/548 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV65813834; called by muse, mutect2
- PNPLA6 | c.2815C>T p.R939C (on ENST00000414982 / NM_001166111.2; = p.R891C on NM_006702.5) | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1191422754; called by muse, mutect2
- PPA1 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs980742623; called by muse, mutect2, varscan2
- RASGRF2 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs747180986; called by muse, mutect2
- RGL3 | c.372-8C>T | Splice Region (SNP) | VAF 15/161 reads (9%) | catalogued as rs368507857, COSV62697015; called by muse, mutect2, varscan2
- SEC61A2 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53651197; called by muse, mutect2
- SEPTIN10 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 12/412 reads (3%) | catalogued as COSV61780225; called by muse, mutect2
- SIGLEC10 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 25/310 reads (8%) | catalogued as rs763006925, COSV59482247; called by muse, mutect2
- SLC45A1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 62/582 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143356185, COSV57097673; called by muse, mutect2, varscan2
- SLK | c.2401G>C p.D801H | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59827912; called by muse, mutect2
- SOX5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58629895; called by muse, mutect2
- TEX11 | c.2140G>A p.E714K (on ENST00000344304; = p.E699K on NM_031276.3) | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100721376; called by muse, mutect2
- TMEFF1 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV58498516; called by mutect2, varscan2
- TMEM119 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67189161; called by muse, mutect2
- TMEM220 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1281277154; called by muse, mutect2
- TPI1 | c.532G>A p.E178K (on ENST00000229270; = p.E141K on NM_000365.6) | Missense Mutation (SNP) | VAF 28/611 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.052); catalogued as COSV99222747; called by muse, mutect2
- TSC2 | c.2647C>T p.Q883* | Nonsense Mutation (SNP) | VAF 42/610 reads (7%) | catalogued as rs45476100, COSV54766714, COSV54773124; ClinVar: not provided; called by muse, mutect2
- TTN | c.52441C>G p.P17481A (on ENST00000591111; = p.P10057A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/406 reads (6%) | PolyPhen probably damaging (0.997); catalogued as COSV59901929; called by muse, mutect2
- ZNF462 | c.4109G>A p.R1370K | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99472931; called by muse, mutect2, varscan2
- ARFGEF2 | c.4391_4398del p.P1464Lfs*3 | Frame Shift Del (DEL) | VAF 48/403 reads (12%) | called by mutect2, pindel
- ATAD2 | c.1818G>C p.E606D | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2
- BAZ1A | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- BRIP1 | c.2530C>G p.L844V | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BTBD8 | c.3622G>T p.E1208* (on ENST00000636805 / NM_001376131.1; = p.E695* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- C12orf75 | c.106C>G p.H36D | Missense Mutation (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- CALCOCO1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 88/515 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CAND2 | c.2435C>G p.S812* (on ENST00000456430 / NM_001162499.2; = p.S719* on NM_012298.3) | Nonsense Mutation (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- CENPC | c.2176C>G p.H726D | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- CFTR | c.3776G>A p.R1259K | Missense Mutation (SNP) | VAF 57/532 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- CHRND | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2
- CLCA4 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COX8C | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- DCAF6 | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 39/420 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2
- EIF4G3 | c.2129G>A p.R710K | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2
- ELMO1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FAM184B | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FBP1 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FNTB | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 41/402 reads (10%) | called by muse, mutect2, varscan2
- GASK1A | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- GLI3 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- GRIN1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C5 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); called by muse, mutect2
- HEATR1 | c.5890G>A p.D1964N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- HLCS | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2
- HNRNPF | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- IL13RA1 | c.1104A>T p.K368N | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- IQCH | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- IRS1 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 26/756 reads (3%) | called by muse, mutect2
- KIAA0232 | c.2989G>C p.E997Q | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.929); called by muse, varscan2
- KIR2DL4 | c.302T>A p.L101Q (on ENST00000396284; = p.L62Q on NM_001080770.2) | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL24 | c.789C>G p.N263K | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- LAMB3 | c.1059G>C p.K353N | Missense Mutation (SNP) | VAF 70/819 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- LYST | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by muse, mutect2
- MAEA | c.685G>A p.E229K (on ENST00000303400 / NM_001017405.3; = p.E188K on NM_005882.5) | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- MAP1A | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MED24 | c.2232C>A p.F744L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2
- MEF2C | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MROH1 | c.1440G>A p.M480I | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- MUC6 | c.4058G>A p.G1353E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- MXRA8 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.013); called by muse, mutect2
- NOS1AP | c.465G>C p.M155I | Missense Mutation (SNP) | VAF 45/487 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); called by muse, mutect2
- NR2E3 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2
- NR5A1 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.49); called by muse, mutect2
- PARD3B | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- PCDHB10 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 25/733 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.51); called by muse, mutect2
- PCDHGB1 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHYHD1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PPP4R1 | c.454C>G p.Q152E (on ENST00000400556 / NM_001042388.3; = p.Q135E on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PREX1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 23/490 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.179); called by muse, mutect2
- PSKH2 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB12 | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- RAB39A | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RBP7 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RECQL4 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2
- RECQL4 | c.2587G>C p.E863Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RINT1 | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2
- RMDN2 | c.820G>A p.E274K (on ENST00000354545 / NM_001322212.2; = p.E452K on NM_144713.5) | Missense Mutation (SNP) | VAF 12/414 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.294); called by muse, mutect2
- RP2 | c.444T>G p.F148L | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- RRS1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- RTL9 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SACM1L | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- SLC39A6 | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 44/376 reads (12%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.1377G>A p.M459I | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SMARCAL1 | c.1322G>C p.R441T | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- SORL1 | c.5420-5C>T | Splice Region (SNP) | VAF 26/311 reads (8%) | called by muse, mutect2
- SPATC1 | c.1207C>G p.R403G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- STK17A | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2
- STS | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); called by muse, mutect2
- STYX | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2
- TPI1 | c.348C>G p.I116M (on ENST00000229270; = p.I79M on NM_000365.6) | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TREH | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- TRIM4 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 14/360 reads (4%) | called by muse, mutect2
- TRIM45 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- TTC7A | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- TTN | c.51955C>T p.Q17319* (on ENST00000591111; = p.Q9895* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/406 reads (6%) | called by muse, mutect2
- UIMC1 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); called by muse, mutect2
- VDAC2 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.486); called by muse, mutect2
- WDR31 | c.325G>A p.V109I (on ENST00000374193 / NM_001006615.3; = p.V108I on NM_145241.5) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2
- WRN | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XPNPEP2 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); called by muse, mutect2
- YDJC | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- YY1 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- YY1 | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB11 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2
- ZFHX4 | c.10057G>C p.E3353Q | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.048); called by muse, mutect2
- ZNF436 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- ZNF646 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- ZNF780A | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- ABCA13 | c.2691T>C p.A897= | Silent (SNP) | VAF 13/462 reads (3%) | called by muse, mutect2
- ACSM5 | c.39G>A p.L13= | Silent (SNP) | VAF 45/343 reads (13%) | catalogued as rs1406811442; called by muse, mutect2, varscan2
- ADGRL3 | c.1521C>A p.T507= (on ENST00000506720 / NM_001322402.2; = p.T439= on NM_015236.6) | Silent (SNP) | VAF 16/310 reads (5%) | catalogued as rs1193300859; called by muse, mutect2
- AEBP2 | c.417G>A p.S139= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- CADM3 | c.771C>T p.R257= (on ENST00000368125 / NM_001127173.3; = p.R291= on NM_021189.5) | Silent (SNP) | VAF 30/318 reads (9%) | catalogued as rs373766355; called by muse, mutect2
- CAND2 | c.1566C>G p.L522= (on ENST00000456430 / NM_001162499.2; = p.L429= on NM_012298.3) | Silent (SNP) | VAF 13/285 reads (5%) | catalogued as rs1395272755; called by muse, mutect2
- CCDC106 | c.777C>G p.L259= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- CDH10 | c.444C>T p.I148= | Silent (SNP) | VAF 17/505 reads (3%) | catalogued as COSV52597563; called by muse, mutect2
- CHST1 | c.477C>T p.V159= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- CREB1 | c.510G>A p.V170= (on ENST00000432329 / NM_134442.5; = p.V156= on NM_004379.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- CUEDC1 | c.717C>T p.F239= | Silent (SNP) | VAF 55/494 reads (11%) | catalogued as rs750025752, COSV64226035; called by muse, mutect2, varscan2
- CUL7 | c.4674G>A p.Q1558= | Silent (SNP) | VAF 49/564 reads (9%) | called by muse, mutect2
- DAGLB | c.18C>G p.L6= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- DNAH1 | c.8487G>A p.K2829= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- ERP27 | c.396G>A p.L132= | Silent (SNP) | VAF 12/399 reads (3%) | catalogued as rs974380655; called by muse, mutect2
- FAM50A | c.30G>A p.E10= | Silent (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- GANAB | c.1458G>A p.L486= | Silent (SNP) | VAF 11/294 reads (4%) | catalogued as rs956741672; called by muse, mutect2
- GGT5 | c.801G>A p.V267= | Silent (SNP) | VAF 69/260 reads (27%) | called by muse, mutect2, varscan2
- IPO11 | c.1938C>A p.L646= | Silent (SNP) | VAF 37/319 reads (12%) | called by muse, mutect2, varscan2
- ITPKB | c.2409C>T p.I803= | Silent (SNP) | VAF 36/326 reads (11%) | called by muse, mutect2, varscan2
- KEL | c.702C>G p.L234= | Silent (SNP) | VAF 38/540 reads (7%) | called by muse, mutect2
- LCP2 | c.180C>T p.L60= | Silent (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- MOV10 | c.780G>A p.R260= | Silent (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- MROH2A | c.2226G>A p.L742= | Silent (SNP) | VAF 35/399 reads (9%) | called by muse, mutect2
- NID2 | c.345G>A p.T115= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as rs553050703, COSV53501601; called by muse, mutect2, varscan2
- NUDT11 | c.294G>A p.L98= | Silent (SNP) | VAF 17/613 reads (3%) | catalogued as rs1314121969; called by muse, mutect2
- PCDHA1 | c.63C>G p.L21= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV65377305; called by muse, mutect2
- PCDHA10 | c.513C>T p.L171= | Silent (SNP) | VAF 16/461 reads (3%) | catalogued as COSV56478108; called by muse, mutect2
- PCDHA13 | c.105C>T p.V35= | Silent (SNP) | VAF 16/434 reads (4%) | catalogued as rs1219477915, COSV56541794; called by muse, mutect2
- PPOX | c.564C>T p.F188= | Silent (SNP) | VAF 59/546 reads (11%) | called by muse, mutect2, varscan2
- PSD2 | c.2256C>A p.L752= | Silent (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- RAD9B | c.1059C>T p.V353= | Silent (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- RPL9 | c.135C>T p.L45= | Silent (SNP) | VAF 78/763 reads (10%) | catalogued as rs199892060; called by muse, mutect2, varscan2
- RPS6KA4 | c.1137G>A p.L379= | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- SATB2 | c.2028G>C p.L676= | Silent (SNP) | VAF 24/541 reads (4%) | catalogued as COSV53478214; called by muse, mutect2
- SBSPON | c.690C>G p.L230= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- SCARB1 | c.1482C>G p.L494= | Silent (SNP) | VAF 40/405 reads (10%) | called by muse, mutect2
- SETD1A | c.981C>T p.I327= | Silent (SNP) | VAF 37/458 reads (8%) | catalogued as rs1220499465, COSV99352866; called by muse, mutect2
- SLC5A10 | c.1362G>A p.V454= (on ENST00000395645 / NM_001042450.4; = p.V470= on NM_152351.5) | Silent (SNP) | VAF 29/266 reads (11%) | called by muse, mutect2, varscan2
- SPTBN4 | c.2616G>A p.L872= | Silent (SNP) | VAF 26/255 reads (10%) | catalogued as COSV58949055; called by muse, mutect2, varscan2
- TMEM132E | c.12G>A p.G4= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as rs772028517; called by muse, mutect2
- TMEM151B | c.825C>G p.L275= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- TMUB1 | c.87C>T p.V29= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1387357205; called by muse, mutect2
- YBX3 | c.711C>T p.F237= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as rs747231634; called by muse, mutect2
- ZNF526 | c.150C>G p.L50= | Silent (SNP) | VAF 32/644 reads (5%) | called by muse, mutect2
- ZNF618 | c.2508G>A p.V836= (on ENST00000374126 / NM_001318042.2; = p.V743= on NM_133374.2) | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as rs1463103470; called by muse, mutect2
- ADAM21P1 | n.1333C>T | RNA (SNP) | VAF 28/360 reads (8%) | catalogued as rs542018285; called by muse, mutect2
- C5orf64 | n.512+8358C>T | Intron (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- DCP1B | c.319+2049G>A | Intron (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2
- DISC1 | c.1981+36511C>G | Intron (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- FAM215A | n.372G>A | RNA (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- KIAA2012 | c.369+1826C>T | Intron (SNP) | VAF 20/267 reads (7%) | called by muse, mutect2
- KRT7 | chr12:52253302 C>G | 3'Flank (SNP) | VAF 42/606 reads (7%) | called by muse, mutect2
- LAMP3 | c.*19G>A | 3'UTR (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- LRRCC1 | c.*38G>C | 3'UTR (SNP) | VAF 7/175 reads (4%) | called by muse, mutect2
- NDUFB5 | c.124+2833C>T | Intron (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- NRIP1 | c.-537-7167C>G | Intron (SNP) | VAF 14/296 reads (5%) | catalogued as rs1307519391; called by muse, mutect2
- NXF5 | n.994G>C | RNA (SNP) | VAF 38/337 reads (11%) | catalogued as rs745648820, COSV53791295, COSV99534107; called by muse, mutect2, varscan2
- RELL1 | c.89-15749C>T | Intron (SNP) | VAF 22/158 reads (14%) | called by muse, varscan2
- SFTA3 | n.810-684G>A | Intron (SNP) | VAF 41/223 reads (18%) | called by muse, mutect2, varscan2
- SYTL2 | c.1388-30C>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- TLCD2 | chr17:1713722 C>G | 5'Flank (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- TPI1 | c.227-547C>T | Intron (SNP) | VAF 20/474 reads (4%) | catalogued as rs1555131873; called by muse, mutect2
- TRAPPC4 | c.*4G>A | 3'UTR (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- TSGA10 | c.-433G>C | 5'UTR (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- VAMP7 | c.*148C>T | 3'UTR (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- WDR20 | chr14:102224598 C>T | 3'Flank (SNP) | VAF 27/244 reads (11%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75516185 G>A | 5'Flank (SNP) | VAF 27/378 reads (7%) | called by muse, mutect2
